Somatic mutation profile of tumor specimen TCGA-BR-A4J4-01A (aliquot TCGA-BR-A4J4-01A-12D-A25D-08) from TCGA case TCGA-BR-A4J4, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 39.6 years (14,459 days).
Specimen TCGA-BR-A4J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ebd03d1-39c7-4192-a9c6-024101c13e23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4J4-10A (Blood Derived Normal), aliquot TCGA-BR-A4J4-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0774d1a0-ebe8-427e-bac1-2b2520ccc8e8

The open-access MAF lists 77 somatic variants for this specimen: 62 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 13, Nonsense Mutation 3, 5'UTR 1, Splice Region 1, 5'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL1 | c.4078G>C p.E1360Q (on ENST00000340736 / NM_001008701.3; = p.E1355Q on NM_014921.5) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.677); catalogued as COSV61564415; called by muse, mutect2, varscan2
- ARHGAP31 | c.652A>C p.N218H | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51791942; called by muse, mutect2, varscan2
- ARID1B | c.5827T>C p.S1943P | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51658905; called by muse, mutect2, varscan2
- CAMSAP3 | c.3719C>T p.T1240I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV50332996; called by muse, mutect2, varscan2
- CCDC185 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754754030, COSV64820292, COSV99081317; called by muse, mutect2, varscan2
- CCDC88C | c.4606G>A p.A1536T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs375420508; called by muse, mutect2, varscan2
- CCZ1 | c.842G>C p.R281T | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1274514149, COSV100382820; called by muse, mutect2, varscan2
- CHD4 | c.3974G>T p.R1325I (on ENST00000357008 / NM_001363606.2; = p.R1338I on NM_001273.5) | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58895972, COSV58909317; called by muse, mutect2, varscan2
- CHD6 | c.7711G>A p.D2571N | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as rs1179703326, COSV64690035; called by muse, mutect2, varscan2
- CMYA5 | c.8670C>A p.S2890R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV71405509; called by muse, mutect2, varscan2
- CNGB1 | c.2986G>A p.G996S | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs546596310, COSV51900003; called by muse, mutect2, varscan2
- COL4A4 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs767194693, COSV61630362, COSV61631425; called by muse, mutect2, varscan2
- COL5A1 | c.4795G>A p.E1599K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as rs149212775, COSV65668143; called by muse, mutect2, varscan2
- CRB2 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1043719019, COSV63502810; called by muse, mutect2, varscan2
- CSAD | c.310G>A p.G104R (on ENST00000444623 / NM_001244705.2; = p.G131R on NM_015989.5) | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs775973649, COSV57242308; called by muse, mutect2, varscan2
- CTNNA3 | c.2374C>A p.L792M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV65523655; called by muse, mutect2, varscan2
- CUBN | c.5138C>T p.T1713M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs764580471, COSV64714055; called by muse, mutect2
- DAPK3 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.05); catalogued as COSV56662827; called by muse, mutect2, varscan2
- EDIL3 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56884291; called by muse, mutect2, varscan2
- EMCN | c.587T>G p.V196G | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56458319; called by muse, mutect2, varscan2
- EMG1 | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54641743; called by muse, mutect2, varscan2
- EPS8L3 | c.1399C>T p.R467W (on ENST00000361965 / NM_133181.4; = p.R437W on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs759149795, COSV62608767, COSV62609288; called by muse, mutect2, varscan2
- FOXP2 | c.1644G>A p.W548* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV63484805; called by muse, mutect2, varscan2
- FSTL5 | c.2228C>A p.A743E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV60191633; called by muse, mutect2, varscan2
- GCM2 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV65275430; called by muse, mutect2, varscan2
- GRIA1 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776137950, COSV53599427; called by muse, mutect2, varscan2
- HSPA12A | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200364186, COSV65021480; called by muse, mutect2, varscan2
- IFT57 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV52709273; called by muse, mutect2, varscan2
- IL7R | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as rs1329201977, COSV57407776; called by muse, mutect2, varscan2
- ITIH1 | c.1993C>T p.R665* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as rs373390489, COSV56254303; called by muse, mutect2, varscan2
- KIFBP | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1031934038, COSV62831622; called by muse, mutect2, varscan2
- KLF12 | c.1028-1G>T p.X343_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100888518; called by muse, mutect2, varscan2
- LGR5 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); catalogued as rs1249686998, COSV57004398; called by muse, mutect2, varscan2
- MTIF2 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs188291557, COSV55050625; called by muse, mutect2, varscan2
- MYOCD | c.1909C>A p.H637N | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.658); catalogued as COSV58502274; called by muse, mutect2, varscan2
- OCEL1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV52243463; called by muse, mutect2, varscan2
- OR2M3 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 99/436 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as COSV101513540, COSV71758998; called by muse, mutect2, varscan2
- OR4C13 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV73648722; called by muse, mutect2, varscan2
- OSBPL6 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV51915807, COSV51930051; called by muse, mutect2, varscan2
- PCDHA8 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.39); catalogued as COSV65337750; called by muse, mutect2, varscan2
- PHYH | c.399C>A p.Y133* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV53815514; called by muse, mutect2, varscan2
- PLSCR4 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34036393; called by muse, mutect2, varscan2
- PROKR2 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs146963803, CM119302; called by muse, mutect2, varscan2
- PRPF8 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV59262647; called by muse, mutect2, varscan2
- PWWP3B | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs373158939, COSV61799340; called by muse, mutect2, varscan2
- RASSF4 | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58485830; called by muse, mutect2, varscan2
- SHPRH | c.4088G>C p.R1363T (on ENST00000275233 / NM_001042683.3; = p.R1367T on NM_173082.3) | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51608246; called by muse, mutect2, varscan2
- SLC6A4 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771843360, COSV55566579; called by muse, mutect2, varscan2
- SRGAP1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.607); catalogued as rs149964620, COSV100754744; called by muse, mutect2, varscan2
- SS18L1 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); catalogued as rs770605211, COSV59210143; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2328C>G p.H776Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV59129388; called by muse, mutect2, varscan2
- TAF4 | c.2126C>T p.T709M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs373706810; called by muse, mutect2, varscan2
- TIMP3 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV56663440; called by muse, mutect2, varscan2
- TNS3 | c.3061G>A p.G1021S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV60790008; called by muse, mutect2, varscan2
- TRIM67 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs371678236, COSV100792188, COSV64159270; called by muse, mutect2, varscan2
- VIT | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64896313; called by muse, mutect2, varscan2
- VWF | c.4276C>T p.R1426C | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs555366738, CM163427, COSV54617848; called by muse, mutect2, varscan2
- ZBTB16 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs780881752, COSV60092102; called by muse, mutect2, varscan2
- ZFPM2 | c.534G>A p.G178= | Splice Region (SNP) | VAF 24/109 reads (22%) | catalogued as COSV65873228; called by muse, mutect2, varscan2
- ZNF160 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs145414197; called by muse, mutect2, varscan2
- ZNF263 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54596186; called by muse, mutect2, varscan2
- BBS2 | c.530_531del p.K177Rfs*7 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.2685G>A p.S895= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1314943507, COSV61261176; called by muse, mutect2, varscan2
- CLCA1 | c.2535G>A p.Q845= | Silent (SNP) | VAF 45/229 reads (20%) | catalogued as COSV52327344; called by muse, mutect2, varscan2
- FCRLA | c.600A>G p.V200= (on ENST00000367959; = p.V177= on NM_032738.4) | Silent (SNP) | VAF 67/283 reads (24%) | catalogued as COSV52685479; called by muse, mutect2, varscan2
- IKZF1 | c.1521G>A p.S507= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV58784808; called by mutect2, varscan2
- LGMN | c.879C>T p.P293= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs1429076314, COSV58403546; called by muse, mutect2, varscan2
- OSGIN2 | c.1398T>G p.V466= | Silent (SNP) | VAF 70/170 reads (41%) | catalogued as rs368417072; called by muse, mutect2, varscan2
- PRR30 | c.769C>A p.R257= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV53205693; called by muse, mutect2, varscan2
- RBM47 | c.1581C>T p.N527= (on ENST00000295971 / NM_001098634.2; = p.N458= on NM_019027.4) | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs1398174441, COSV55933908; called by muse, mutect2, varscan2
- RNF20 | c.2157C>A p.A719= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV66660904; called by muse, mutect2
- SH3BP5L | c.402G>A p.A134= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs756594510, COSV63538903; called by muse, mutect2, varscan2
- SPIN1 | c.465C>T p.V155= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV65499172; called by muse, mutect2, varscan2
- SYNE2 | c.14040G>C p.V4680= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV59947980; called by muse, mutect2, varscan2
- TBX4 | c.939C>T p.L313= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as rs777644345, COSV53606573, COSV53610218; called by muse, mutect2, varscan2
- MFRP | chr11:119346323 G>A | 5'Flank (SNP) | VAF 19/66 reads (29%) | catalogued as COSV64128274; called by muse, mutect2, varscan2
- PRRC1 | c.-2A>G | 5'UTR (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99687838; called by muse, mutect2, varscan2
